Somatic mutation profile of tumor specimen TCGA-AJ-A3EJ-01A (aliquot TCGA-AJ-A3EJ-01A-11D-A19Y-09) from TCGA case TCGA-AJ-A3EJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 74.8 years (27,317 days).
Specimen TCGA-AJ-A3EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7fa27ea-1bea-4387-93d7-781286a80904.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3EJ-10A (Blood Derived Normal), aliquot TCGA-AJ-A3EJ-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/850de5e6-eeaf-4d2a-bb17-a6691a5fe0f9

The open-access MAF lists 62 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 12, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 2, RNA 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 125/147 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AFM | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as rs536766988, COSV56919890; called by muse, mutect2, varscan2
- AGBL5 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201033068; called by muse, mutect2, varscan2
- ALDOA | c.232G>A p.V78M (on ENST00000642816 / NM_001243177.4; = p.V24M on NM_184041.5) | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.71); catalogued as rs1567322810, COSV100582028; called by muse, mutect2, varscan2
- ARHGAP4 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV100509495, COSV61687056; called by muse, mutect2, varscan2
- ARHGAP4 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs782798048, COSV100604012; called by muse, mutect2, varscan2
- C12orf66 | c.718C>A p.L240M | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.982); catalogued as COSV100320685, COSV61322944, COSV61324099; called by muse, mutect2, varscan2
- CAGE1 | c.1784G>T p.C595F (on ENST00000512086; = p.C459F on NM_205864.3) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.568); catalogued as COSV99699604; called by muse, mutect2, varscan2
- CD163 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100775807; called by muse, mutect2, varscan2
- CHD4 | c.3275G>T p.R1092L (on ENST00000357008 / NM_001363606.2; = p.R1105L on NM_001273.5) | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100537532, COSV100537818, COSV58899203; called by muse, mutect2, varscan2
- DHX58 | c.1754+1G>T p.X585_splice | Splice Site (SNP) | VAF 43/72 reads (60%) | catalogued as COSV99288196; called by muse, mutect2, varscan2
- DPYSL5 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV99982240; called by muse, mutect2, varscan2
- GALNT6 | c.988G>A p.G330S | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs775170955, COSV100695416; called by muse, mutect2, varscan2
- HUWE1 | c.10255G>T p.G3419W | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs1556924813, COSV99471796; called by muse, mutect2, varscan2
- IL5 | c.16C>A p.H6N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99185048; called by muse, mutect2, varscan2
- KLHL41 | c.1742T>A p.M581K | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV99500339; called by muse, mutect2, varscan2
- KMT2D | c.9981G>T p.Q3327H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV99980586; called by muse, mutect2, varscan2
- LIN28A | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54261617; called by muse, mutect2, varscan2
- LRRTM3 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63669660; called by muse, mutect2, varscan2
- MACF1 | c.16174C>G p.R5392G (on ENST00000372915; = p.R3325G on NM_012090.5) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99243656; called by muse, mutect2, varscan2
- MAGEA3 | c.761A>T p.N254I | Missense Mutation (SNP) | VAF 20/273 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100939040; called by muse, mutect2
- NF1 | c.5588G>A p.G1863D (on ENST00000358273 / NM_001042492.3; = p.G1842D on NM_000267.3) | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62207272, COSV62212777; called by muse, mutect2, varscan2
- OR4C13 | c.167C>G p.P56R | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV101634171, COSV101634225; called by muse, mutect2, varscan2
- OR8H3 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as rs1400753248, COSV57910448; called by muse, mutect2
- PASD1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761622222, COSV64854816; called by muse, mutect2, varscan2
- PKP1 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.946); catalogued as COSV99825225; called by muse, mutect2, varscan2
- PRPF3 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as rs782318341, COSV61394444; called by muse, mutect2, varscan2
- PRR12 | c.1327G>C p.E443Q (on ENST00000615927; = p.E1264Q on NM_020719.3) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV101330646, COSV69817882; called by muse, mutect2, varscan2
- PSME4 | c.2129G>T p.C710F | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV66363563, COSV66366544; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2840G>A p.R947H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756956146, COSV99920982; called by muse, mutect2, varscan2
- RAB3IL1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs140445882, COSV100076553; called by muse, mutect2, varscan2
- SLC15A1 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs200210206, COSV64712727; called by muse, mutect2, varscan2
- SPATA4 | c.557A>T p.K186M | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.356); catalogued as rs754218277, COSV99708936; called by muse, mutect2, varscan2
- SPOCK2 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs200859576, COSV100436360; called by muse, mutect2, varscan2
- SRPRA | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55005101, COSV99702768, COSV99702805; called by muse, mutect2, varscan2
- STAT3 | c.1387G>T p.V463L | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV99232708; called by muse, mutect2, varscan2
- TKTL1 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs781826654, COSV54212671; called by muse, mutect2, varscan2
- TRABD | c.114C>T p.S38= | Splice Region (SNP) | VAF 34/96 reads (35%) | catalogued as rs375977248; called by muse, mutect2, varscan2
- TRMT6 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 12/202 reads (6%) | catalogued as COSV99177559; called by muse, mutect2
- UNC13B | c.3269G>A p.R1090Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs776483798, COSV101036589; called by muse, mutect2, varscan2
- ZNF831 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV64038721; called by muse, mutect2, varscan2
- ZSWIM2 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201691052, COSV99720136; called by muse, mutect2, varscan2
- ZUP1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 49/233 reads (21%) | catalogued as rs996142006, COSV100884985; called by muse, mutect2, varscan2
- ANKRD11 | c.1317_1318del p.E441Afs*3 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | called by pindel, varscan2
- IGKV1-12 | c.49T>A p.F17I | Missense Mutation (SNP) | VAF 102/588 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R1 | c.1193del p.F398Sfs*7 (on ENST00000521381 / NM_181523.3; = p.F128Sfs*7 on NM_181504.4) | Frame Shift Del (DEL) | VAF 50/113 reads (44%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1677_1679del p.D560del (on ENST00000521381 / NM_181523.3; = p.D290del on NM_181504.4) | In Frame Del (DEL) | VAF 25/116 reads (22%) | called by mutect2, pindel, varscan2
- REXO1 | c.3028del p.W1010Gfs*36 | Frame Shift Del (DEL) | VAF 48/94 reads (51%) | called by mutect2, pindel, varscan2
- TP53 | c.424_426del p.P142del | In Frame Del (DEL) | VAF 25/48 reads (52%) | called by mutect2, pindel, varscan2
- ADD2 | c.1800T>G p.S600= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100035463; called by muse, mutect2, varscan2
- DOCK6 | c.2892C>T p.F964= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs893427655, COSV99625392; called by muse, mutect2, varscan2
- KCTD19 | c.528C>T p.F176= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as COSV100430878; called by muse, mutect2, varscan2
- KRI1 | c.159C>T p.D53= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100224791; called by muse, mutect2, varscan2
- LRPPRC | c.2508C>T p.G836= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1279013600, COSV99580461; called by muse, mutect2
- NLRP7 | c.1440C>T p.Y480= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs201781231, COSV100052394, COSV100053391; called by muse, mutect2, varscan2
- POF1B | c.1494C>T p.D498= | Silent (SNP) | VAF 15/190 reads (8%) | catalogued as COSV99426563; called by muse, mutect2
- PPP2R2B | c.666G>A p.T222= (on ENST00000394409; = p.T288= on NM_181674.2) | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs779770096, COSV60752666; called by muse, mutect2, varscan2
- RFTN1 | c.1194G>A p.A398= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs760229079, COSV100489187; called by muse, mutect2, varscan2
- RHOXF2B | c.417C>T p.H139= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs1555996235, COSV101003955; called by muse, mutect2, varscan2
- ST14 | c.807C>T p.D269= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs764272121, COSV53834194; called by muse, mutect2, varscan2
- TMEM141 | c.15T>G p.G5= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV99264382; called by muse, varscan2
- SSPOP | n.14480C>T | RNA (SNP) | VAF 25/72 reads (35%) | catalogued as COSV100947292; called by muse, mutect2, varscan2
